Surgical pathology report (de-identified scan), TCGA case TCGA-B2-5633, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B2-5633-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

Right kidney

CLINICAL NOTES

PRE-OP DIAGNOSIS: Right renal mass.

GROSS DESCRIPTION

Received fresh, for tissue procurement labeled "right kidney" is a 12.0 x 6.5 x 5.5 cm. right kidney with attached, probe patent, 4.5 cm. ureter averaging 0.3 cm. and a copious amount of perirenal adipose tissue. No adrenal tissue is evident. On sectioning, there is a well-circumscribed, 5.8 x 3.5 x 3.5 cm. tan gold-red tumor mass centrally which approaches the inked

capsular surface to within 0.15 cm. A portion of tumor and a portion of normal parenchyma are submitted for tissue procurement as requested. The renal pelvis is smooth glistening tan white. Uninvolved parenchyma is uniform red brown with a well-defined corticomedullary junction and a maximal cortical thickness of 1.2 cm. No additional mass lesion or abnormality is identified. Representative sections are submitted in 9 blocks as labeled. RS9.

BLOCK SUMMARY: 1 - Vascular and ureteral margins; 2-4 - tumor to inked capsular surface; 5 and 6 - tumor to normal p chyma; 7 - renal pelvis; 8 and 9 - random normal parenchyma.

MICROSCOPIC DESCRIPTION

In the mid portion of this kidney there is a 5.8 cm. clear cell renal cortical carcinoma, confined to the kidney. Please see the template below.

Histologic type: Clear cell carcinoma.

Histologic grade (Fuhrman Nuclear Grade): 2

[page 2 of 2]
MICROSCOPIC DESCRIPTION

Primary tumor (pT): pT1b.
Margins of resection: Negative for tumor.
Regional lymph nodes (pN): Cannot be assessed.
Distant metastasis (pM): Cannot be assessed.
Adrenal gland: Not present.
Vascular invasion: Negative.
Non-neoplastic kidney: Rare intratubular calcification.
Other findings: None.

4

DIAGNOSIS

Right kidney, nephrectomy -
Kidney with clear cell renal cortical carcinoma, pT1b. All
margins are negative for tumor.

--- End Of Report ---

Source: NCI Genomic Data Commons file a24ca0cc-4c9a-418a-b862-0e8dd6746b7c (TCGA-B2-5633.5EA82B70-910B-4068-8A71-9BF766B0CFAB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).